Somatic mutation profile of tumor specimen TCGA-97-8171-01A (aliquot TCGA-97-8171-01A-11D-2284-08) from TCGA case TCGA-97-8171, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 81.1 years (29,627 days).
Specimen TCGA-97-8171-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dec2238d-eb92-482c-8f72-ad4a9dfb2df1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-8171-10A (Blood Derived Normal), aliquot TCGA-97-8171-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c9219ac-cf5f-4ab9-9bf3-5ff16a4ab1ff

The open-access MAF lists 57 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Nonsense Mutation 4, Intron 1, Frame Shift Del 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 41/85 reads (48%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ARID5A | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs768451723, COSV100673511; called by muse, mutect2, varscan2
- ASB15 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as rs1376721710, COSV51924653; called by muse, mutect2, varscan2
- CACNA1C | c.4997G>A p.R1666Q | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100217622, COSV59753041; called by muse, mutect2
- CCDC144A | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.908); catalogued as rs1404101186, COSV100502013; called by muse, mutect2, varscan2
- CDHR2 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56134621; called by muse, mutect2, varscan2
- COL7A1 | c.4721G>A p.R1574Q | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.681); catalogued as rs550333338; called by muse, mutect2, varscan2
- CSMD3 | c.9184C>T p.P3062S (on ENST00000297405 / NM_001363185.1; = p.P2893S on NM_052900.3) | Missense Mutation (SNP) | VAF 71/116 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs373608234; called by muse, mutect2, varscan2
- CYFIP2 | c.3790C>T p.R1264C (on ENST00000616178 / NM_001291722.2; = p.R1239C on NM_014376.4) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs371399881; called by muse, mutect2, varscan2
- F7 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as rs121964929, CM940391; called by muse, mutect2, varscan2
- FAM83B | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569347325, COSV100173941; called by muse, mutect2, varscan2
- KCTD8 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 68/141 reads (48%) | catalogued as COSV63586161; called by muse, mutect2, varscan2
- LAMTOR4 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 30/147 reads (20%) | catalogued as COSV100553024; called by muse, mutect2, varscan2
- MBD5 | c.3253G>A p.V1085I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as rs199626531, COSV68695492; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MCHR1 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs754405878, COSV50760721; called by muse, mutect2, varscan2
- NRSN1 | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs758914459; called by muse, mutect2, varscan2
- SIPA1L3 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs781621277; called by muse, mutect2, varscan2
- SLC24A4 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as rs1297436330, COSV54108356; called by muse, mutect2, varscan2
- SLC8A3 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs1468241871, COSV63520523; called by muse, mutect2, varscan2
- TNFAIP2 | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.302); catalogued as rs140309001; called by muse, mutect2, varscan2
- TRAPPC1 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1270069778; called by muse, mutect2, varscan2
- ACTR1B | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ADRB1 | c.770A>T p.K257M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AP3B2 | c.3117G>T p.R1039S (on ENST00000261722; = p.R1033S on NM_004644.5) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- APBB1 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CES5A | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT tolerated (0.34); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- EIF2AK1 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- FCRL4 | c.619T>A p.S207T | Missense Mutation (SNP) | VAF 68/310 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- HEPH | c.1204A>G p.T402A (on ENST00000343002; = p.T135A on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- KDM5A | c.3317A>T p.D1106V | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MAP2K7 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- MECOM | c.2757T>A p.S919R (on ENST00000468789 / NM_001105078.4; = p.S1107R on NM_004991.4) | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- MRPL47 | c.457del p.L153* | Frame Shift Del (DEL) | VAF 44/113 reads (39%) | called by mutect2, pindel, varscan2
- NXPE3 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ORC1 | c.1592A>T p.Y531F | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PGM2 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- POLDIP3 | c.515T>G p.V172G | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- POLQ | c.5330C>A p.P1777H | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- PREP | c.1678G>C p.D560H (on ENST00000369110; = p.D626H on NM_002726.5) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RTP1 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC22A11 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEFF1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CSF3R | c.1554C>G p.V518= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- GCC2 | c.1248C>T p.C416= | Silent (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- GPX8 | c.621G>A p.E207= | Silent (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- HOXC8 | c.267T>C p.Y89= | Silent (SNP) | VAF 102/224 reads (46%) | catalogued as rs777616754, COSV50000987; called by muse, mutect2, varscan2
- LTA | c.516G>A p.A172= | Silent (SNP) | VAF 79/342 reads (23%) | catalogued as rs368380570; called by muse, mutect2, varscan2
- MSLN | c.987G>A p.A329= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs1369219867; called by muse, mutect2, varscan2
- NUP188 | c.4686G>A p.L1562= | Silent (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- PLIN3 | c.543G>A p.L181= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as rs528975808; called by muse, mutect2, varscan2
- SHANK2 | c.2568A>G p.L856= | Silent (SNP) | VAF 40/114 reads (35%) | called by muse, mutect2, varscan2
- SORCS1 | c.1215G>A p.P405= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs1175757854, COSV53841549, COSV53861871; called by muse, varscan2
- TRIM42 | c.1080C>T p.I360= | Silent (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- ZNF423 | c.3858G>A p.T1286= (on ENST00000563137 / NM_001379286.1; = p.T1278= on NM_015069.4) | Silent (SNP) | VAF 51/57 reads (89%) | called by muse, mutect2, varscan2
- ZNF479 | c.129T>C p.D43= | Silent (SNP) | VAF 28/235 reads (12%) | catalogued as COSV100482662; called by muse, mutect2
- ETNK2 | c.519-798G>T | Intron (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
